Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81Q-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date:

Material: right adrenal

This is a soft gray to reddish tumor with a diameter of 10cm. There is a more light-colored area of about 4 cm.

Histologically, the tumor is composed of zellballen. Cells display marked pleomorphic nuclei. Focal cells have melanin-pigmented to melanin globules with a tan cytoplasm. At several areas, a ganglionic differentiation is detectable with peripheral nuclei and central eosinophil cytoplasm and long cytoplasmic extension. No invasion into vessels.

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3

Pheochromocytoma NOS 87003

Site: (R) Adrenal gland C74.9

JPW 10/17/13

Source: NCI Genomic Data Commons file 8494adda-5c9a-46f3-a27f-058f12de6df8 (TCGA-WB-A81Q.0042742F-E950-4F32-A2B7-5BF199FF58D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).